Somatic mutation profile of tumor specimen TCGA-2G-AAGE-01A (aliquot TCGA-2G-AAGE-01A-21D-A42Y-10) from TCGA case TCGA-2G-AAGE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 21.2 years (7,753 days).
Specimen TCGA-2G-AAGE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebd97ec2-4cc2-478a-bb53-271a0c5ca006.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGE-10A (Blood Derived Normal), aliquot TCGA-2G-AAGE-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b84c1d3-1df2-4e6f-a9ac-4b29c59597ca

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV2 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1242913717; called by muse, mutect2
- ITGB3 | c.1813G>A p.G605S | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144884023, CM981082; called by muse, mutect2, varscan2
- NF1 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs771089333, CD972347, COSV62200671, COSV62212598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCYT1B | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs755263205; called by muse, mutect2, varscan2
- CFAP44 | c.2141T>A p.M714K | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, varscan2
- CNBP | c.390dup p.D131Rfs*9 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- EMID1 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPC2 | c.207del p.E70Rfs*39 | Frame Shift Del (DEL) | VAF 92/330 reads (28%) | called by mutect2, varscan2
- NACAD | c.3025G>T p.A1009S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCLO | c.3761C>T p.T1254I | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYNJ2 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- TBC1D9 | c.2989T>A p.S997T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- TMEM94 | c.571A>T p.R191W | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ASAP3 | c.1350G>T p.T450= | Silent (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- BBS9 | c.1380C>T p.Y460= | Silent (SNP) | VAF 91/424 reads (21%) | catalogued as rs376024532; called by muse, mutect2, varscan2
- BICC1 | c.1896A>G p.R632= | Silent (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- ATG4C | c.1089+547C>G | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CCDC144B | n.399G>A | RNA (SNP) | VAF 57/205 reads (28%) | catalogued as rs1197309802; called by muse, mutect2, varscan2
- PRMT2 | c.654+2116G>A | Intron (SNP) | VAF 33/161 reads (20%) | called by muse, mutect2, varscan2
- RCC1 | c.73+646C>T | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs979136705; called by muse, mutect2
